Somatic mutation profile of tumor specimen MMRF_2504_1_BM_CD138pos (aliquot MMRF_2504_1_BM_CD138pos_T1_KHS5U_L11636) from MMRF case MMRF_2504, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 32.4 years (11,848 days).
Specimen MMRF_2504_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f846b9d-a46a-406d-b220-805760693210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2504_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2504_1_PB_Whole_C2_KHS5U_L11637; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95d36504-0a91-415e-b39e-91d0224f9fde

The open-access MAF lists 93 somatic variants for this specimen: 41 protein-altering or splice-affecting, 13 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 3'UTR 18, Silent 13, Intron 9, 5'UTR 5, 5'Flank 5, Nonsense Mutation 2, 3'Flank 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, varscan2
- ATP6V1B2 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as COSV52353346, COSV99369275; called by muse, mutect2, varscan2
- C4orf50 | c.655G>A p.A219T (on ENST00000324058; = p.A1451T on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.439); catalogued as rs758974747, COSV100135932, COSV60687321; called by muse, mutect2, varscan2
- CDCA7L | c.1154G>A p.R385Q | Missense Mutation (SNP) | VAF 69/349 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60983497; called by muse, mutect2, varscan2
- CPAMD8 | c.4081G>A p.A1361T (on ENST00000651564; = p.A1314T on NM_015692.5) | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs1268148596; called by muse, mutect2
- CSMD2 | c.8858G>T p.G2953V | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895979481; called by muse, mutect2, varscan2
- IGHV2-70 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 42/46 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs191880827; called by muse, varscan2
- IGHV2-70D | c.122G>A p.C41Y | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194006557; called by muse, varscan2
- IGKJ5 | c.35T>A p.I12N | Missense Mutation (SNP) | VAF 86/150 reads (57%) | catalogued as rs375748803; called by muse, varscan2
- IGLV3-1 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 91/177 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs527556136; called by muse, varscan2
- PRPS1L1 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 111/249 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV101552907, COSV72649858; called by muse, mutect2, varscan2
- SAGE1 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 111/116 reads (96%) | SIFT tolerated (0.73); PolyPhen benign (0.184); catalogued as rs782691323, COSV61012032; called by muse, mutect2, varscan2
- TDRD12 | c.1302T>G p.N434K | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1320718056; called by muse, mutect2, varscan2
- ZNF396 | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV60473804; called by muse, mutect2
- ABCA10 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ADAMTS16 | c.2137A>G p.I713V | Missense Mutation (SNP) | VAF 60/116 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARL6IP5 | c.85A>T p.I29F | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CAB39 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CACNA1C | c.4727-5T>C | Splice Region (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.1724G>T p.R575I | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- CDH11 | c.1277A>C p.D426A | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTNAP4 | c.253C>A p.L85I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUSP2 | c.383_387dup p.G130Cfs*113 | Frame Shift Ins (INS) | VAF 48/108 reads (44%) | called by mutect2, pindel, varscan2
- EFNA3 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.267); called by muse, mutect2
- GPR1 | c.403C>T p.H135Y | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.207); called by muse, mutect2
- HDAC9 | c.2351C>A p.A784D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV3-53 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 230/835 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MOGAT1 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2
- NMT2 | c.254G>C p.S85T | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- PEG3 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2
- SERPIND1 | c.904A>T p.K302* | Nonsense Mutation (SNP) | VAF 5/120 reads (4%) | called by muse, mutect2
- SETDB1 | c.2309T>C p.L770P | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLCO2B1 | c.1861G>T p.A621S | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, varscan2
- STAB2 | c.6470A>G p.Y2157C | Missense Mutation (SNP) | VAF 96/208 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK3 | c.428T>G p.I143R | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D13 | c.5C>G p.S2* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | called by mutect2, varscan2
- TMC2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TTN | c.48035G>T p.G16012V (on ENST00000591111; = p.G8588V on NM_003319.4) | Missense Mutation (SNP) | VAF 46/198 reads (23%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VRTN | c.569T>C p.I190T | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- YY1 | c.1063-5G>A | Splice Region (SNP) | VAF 34/37 reads (92%) | called by muse, varscan2
- ZNF799 | c.1019A>G p.K340R | Missense Mutation (SNP) | VAF 136/290 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC135068.1 | c.27G>A p.V9= | Silent (SNP) | VAF 31/112 reads (28%) | called by muse, mutect2, varscan2
- EML3 | c.873G>A p.G291= | Silent (SNP) | VAF 34/226 reads (15%) | called by muse, mutect2, varscan2
- ERC1 | c.2034G>T p.L678= (on ENST00000360905 / NM_178040.4; = p.L650= on NM_178039.4) | Silent (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- ETV5 | c.54A>C p.R18= | Silent (SNP) | VAF 15/194 reads (8%) | called by muse, mutect2
- GLDC | c.2997T>A p.V999= | Silent (SNP) | VAF 55/115 reads (48%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.210A>G p.A70= | Silent (SNP) | VAF 56/145 reads (39%) | called by muse, varscan2
- IGLV3-1 | c.342A>G p.A114= | Silent (SNP) | VAF 61/142 reads (43%) | catalogued as rs750027938; called by muse, varscan2
- NR1H4 | c.1413C>T p.N471= (on ENST00000551379 / NM_001206993.2; = p.N457= on NM_005123.4) | Silent (SNP) | VAF 112/247 reads (45%) | catalogued as rs375712677; called by muse, mutect2, varscan2
- RPL27A | c.187T>C p.L63= | Silent (SNP) | VAF 23/298 reads (8%) | called by muse, mutect2
- SLC44A4 | c.1719A>G p.S573= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as rs1260063237; called by muse, mutect2
- TJP1 | c.24C>A p.A8= | Silent (SNP) | VAF 18/56 reads (32%) | called by mutect2, varscan2
- TMEM43 | c.147A>T p.L49= | Silent (SNP) | VAF 67/118 reads (57%) | called by muse, mutect2, varscan2
- VIRMA | c.3598T>C p.L1200= | Silent (SNP) | VAF 76/174 reads (44%) | called by muse, mutect2
- AC069544.2 | c.*695C>G | 3'UTR (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- ACADL | chr2:210225472 G>T | 5'Flank (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- AL096814.1 | c.*12A>G | 3'UTR (SNP) | VAF 40/166 reads (24%) | called by muse, mutect2, varscan2
- ATXN2 | c.3913+293T>A | Intron (SNP) | VAF 16/296 reads (5%) | called by muse, mutect2
- BCL7A | chr12:122021254 A>C | 5'Flank (SNP) | VAF 59/132 reads (45%) | catalogued as COSV55847825; called by muse, varscan2
- BCL7A | chr12:122021298 T>C | 5'Flank (SNP) | VAF 62/124 reads (50%) | catalogued as rs878943919, COSV55847829; called by muse, varscan2
- BCL7A | chr12:122021659 A>G | 5'Flank (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- BIRC6 | c.*383A>G | 3'UTR (SNP) | VAF 44/83 reads (53%) | called by muse, mutect2, varscan2
- BTG2 | c.-48C>T | 5'UTR (SNP) | VAF 36/151 reads (24%) | catalogued as rs918372024, COSV51857290; called by muse, mutect2, varscan2
- C11orf87 | c.*1944C>T | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- C20orf173 | c.-218-46A>T | Intron (SNP) | VAF 132/308 reads (43%) | called by muse, mutect2, varscan2
- CCN2 | c.*525G>A | 3'UTR (SNP) | VAF 13/36 reads (36%) | catalogued as rs142745505; called by muse, mutect2, varscan2
- CCNC | c.347-198G>A | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- CDH2 | c.*980A>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- CDH2 | c.*841T>A | 3'UTR (SNP) | VAF 32/52 reads (62%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93731566 A>G | 3'Flank (SNP) | VAF 62/125 reads (50%) | called by muse, mutect2, varscan2
- CES3 | c.*1075C>T | 3'UTR (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- COL4A4 | c.*2792A>C | 3'UTR (SNP) | VAF 55/117 reads (47%) | called by muse, mutect2, varscan2
- DDB1 | c.3216-17T>G | Intron (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- DST | c.19135-164T>G | Intron (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- ENAH | c.*4766A>G | 3'UTR (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- FAM160B2 | c.*496G>A | 3'UTR (SNP) | VAF 36/180 reads (20%) | called by muse, mutect2, varscan2
- FBXW8 | chr12:117029416 A>T | 3'Flank (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- FUT4 | c.*3273T>A | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- HMGA2 | c.250-36147C>T | Intron (SNP) | VAF 19/83 reads (23%) | catalogued as rs1313648602; called by muse, mutect2, varscan2
- IGKV4-1 | c.-36T>C | 5'UTR (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2
- KLHL6 | c.*3712A>G | 3'UTR (SNP) | VAF 156/287 reads (54%) | called by muse, mutect2, varscan2
- LZTS2 | c.-722C>G | 5'UTR (SNP) | VAF 22/116 reads (19%) | called by muse, mutect2, varscan2
- MGRN1 | c.562-137C>T | Intron (SNP) | VAF 12/86 reads (14%) | catalogued as rs772866822; called by muse, varscan2
- MIR5195 | chr14:106851238 C>T | 5'Flank (SNP) | VAF 122/255 reads (48%) | catalogued as rs550463544; called by muse, mutect2, varscan2
- NTNG2 | c.*573A>G | 3'UTR (SNP) | VAF 114/219 reads (52%) | called by muse, mutect2, varscan2
- NTRK2 | c.1585+4425G>T | Intron (SNP) | VAF 144/326 reads (44%) | called by muse, mutect2, varscan2
- PEG10 | c.*4724G>A | 3'UTR (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- PTEN | c.*4686A>G | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- PTP4A2 | c.-83G>A | 5'UTR (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- SERPINB6 | c.48-1097T>C | Intron (SNP) | VAF 44/113 reads (39%) | called by muse, mutect2, varscan2
- SNN | c.*628dup | 3'UTR (INS) | VAF 31/116 reads (27%) | catalogued as rs1456550295; called by mutect2, pindel, varscan2
- SUN3 | c.-150G>A | 5'UTR (SNP) | VAF 46/101 reads (46%) | catalogued as rs1034480924; called by muse, varscan2
- TCEANC | c.*1771_*1772del | 3'UTR (DEL) | VAF 4/40 reads (10%) | called by pindel, varscan2
